Somatic mutation profile of tumor specimen TCGA-VV-A829-01A (aliquot TCGA-VV-A829-01A-21D-A36O-08) from TCGA case TCGA-VV-A829, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 44.3 years (16,163 days).
Specimen TCGA-VV-A829-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 449639be-688d-4107-b991-5f1c92a3474a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VV-A829-10A (Blood Derived Normal), aliquot TCGA-VV-A829-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a00e8e29-16b6-45f9-93cb-a909b27e67bf

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 4, Intron 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKLE1 | c.1898C>T p.P633L (on ENST00000394458; = p.P579L on NM_152363.6) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as rs770708931, COSV101082191; called by muse, mutect2
- ANKS4B | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1043739002, COSV100289775; called by muse, mutect2, varscan2
- APEX1 | c.867C>G p.H289Q | Missense Mutation (SNP) | VAF 62/87 reads (71%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99164460; called by muse, mutect2, varscan2
- APOA4 | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100759301; called by muse, mutect2
- BCOR | c.5062G>T p.E1688* (on ENST00000378444 / NM_001123385.2; = p.E1654* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 26/30 reads (87%) | catalogued as COSV100653125; called by muse, mutect2, varscan2
- C2orf76 | c.149C>G p.T50S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs762821520, COSV100601654; called by muse, mutect2, varscan2
- CFHR4 | c.1664C>T p.A555V (on ENST00000367416 / NM_001201551.2; = p.A309V on NM_006684.5) | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.214); catalogued as rs576733857, COSV52225996; called by muse, mutect2, varscan2
- DIS3L | c.2125C>T p.H709Y (on ENST00000319212 / NM_001143688.3; = p.H626Y on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100055104; called by muse, mutect2, varscan2
- EIF4A1 | c.942T>G p.I314M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV99548857; called by muse, mutect2, varscan2
- ESR1 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.842); catalogued as rs182943916, CM057965, COSV52798751; called by muse, mutect2, varscan2
- FLG | c.7207C>T p.R2403W | Missense Mutation (SNP) | VAF 151/303 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); catalogued as rs372607458, COSV64245001; called by muse, mutect2, varscan2
- FNDC1 | c.3982C>G p.P1328A | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs1054846081, COSV99795439; called by muse, mutect2, varscan2
- MAN2B2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs758431473, COSV53452905, COSV99577258; called by muse, mutect2
- PPRC1 | c.2344C>T p.L782F | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV99531549; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2263T>C p.F755L | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99920923; called by muse, mutect2
- RTP1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV56618487; called by muse, mutect2, varscan2
- SNX27 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100919004; called by muse, mutect2, varscan2
- SPRTN | c.1358T>C p.M453T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99149646; called by muse, mutect2, varscan2
- TAS2R7 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344212151, COSV99553712; called by muse, mutect2, varscan2
- TLK2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV100408964; called by muse, mutect2, varscan2
- TMPO | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.277); catalogued as rs772961073, COSV99701956; called by muse, mutect2, varscan2
- ZAN | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs766747166, COSV100769549, COSV61804888; called by muse, mutect2, varscan2
- ZBTB18 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM129356, COSV62396804; called by muse, mutect2, varscan2
- GOLGA6L22 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- NOTCH1 | c.2341del p.E781Rfs*21 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- COLGALT1 | c.969G>A p.E323= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99394939; called by muse, mutect2, varscan2
- DYSF | c.5632C>T p.L1878= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV99245881; called by muse, mutect2, varscan2
- FBXW10 | c.2559G>A p.R853= | Silent (SNP) | VAF 50/161 reads (31%) | catalogued as rs550117830, COSV100111320, COSV57061075; called by muse, mutect2, varscan2
- OR5AS1 | c.30T>C p.T10= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs1217002111, COSV100546224; called by muse, mutect2, varscan2
- DST | c.4296+4334_4296+4337del | Intron (DEL) | VAF 24/74 reads (32%) | catalogued as rs1190413927; called by pindel, varscan2
- SUGP1 | c.539-155T>G | Intron (SNP) | VAF 76/177 reads (43%) | catalogued as COSV99894882; called by muse, mutect2, varscan2
